Somatic mutation profile of tumor specimen TCGA-XF-AAN2-01A (aliquot TCGA-XF-AAN2-01A-11D-A42E-08) from TCGA case TCGA-XF-AAN2, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 73.2 years (26,720 days).
Specimen TCGA-XF-AAN2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d68e68a-4c6c-4178-993d-9dfcf7b8d85a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAN2-10A (Blood Derived Normal), aliquot TCGA-XF-AAN2-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/463f3a8a-bbdc-42ec-905c-ce3be0086cbe

The open-access MAF lists 520 somatic variants for this specimen: 373 protein-altering or splice-affecting, 133 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 323, Silent 133, Nonsense Mutation 28, Splice Site 10, Splice Region 5, Intron 4, Frame Shift Del 4, RNA 4, 3'Flank 2, 5'Flank 2, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 119/357 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 34/107 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PPP2R5D | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs863225081, CM1513244, COSV55150565; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1411C>T p.Q471* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as rs1354030520, COSV57298415; ClinVar: likely pathogenic; called by muse, mutect2
- RYR1 | c.14659C>T p.H4887Y | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs118192147, CM073327, COSV62095618; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SLC2A2 | c.613-1G>C p.X205_splice | Splice Site (SNP) | VAF 18/66 reads (27%) | catalogued as rs1553786361, COSV58585761; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.2080C>T p.L694F | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs1376197004, COSV66065783; called by muse, mutect2, varscan2
- ABCC8 | c.2758G>T p.E920* | Nonsense Mutation (SNP) | VAF 53/154 reads (34%) | catalogued as COSV100216526; called by muse, mutect2, varscan2
- ABHD17C | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51917276; called by muse, mutect2, varscan2
- ABT1 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782567643, COSV51291121; called by muse, mutect2, varscan2
- ACE | c.1451C>A p.P484H | Missense Mutation (SNP) | VAF 112/288 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.43); catalogued as COSV52006084; called by muse, varscan2
- ADAM21 | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV99960426; called by muse, mutect2, varscan2
- ADAMTS9 | c.2957C>A p.P986Q | Missense Mutation (SNP) | VAF 177/426 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55779958; called by muse, mutect2, varscan2
- ADCY2 | c.2531A>G p.E844G | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV57869801; called by muse, mutect2, varscan2
- ADGRG2 | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 129/163 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV61338669; called by muse, mutect2, varscan2
- ADGRG4 | c.4906G>A p.A1636T | Missense Mutation (SNP) | VAF 137/176 reads (78%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1299892058, COSV54954703, COSV54955961; called by muse, mutect2, varscan2
- ADH7 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs752622487, COSV52920599; called by muse, mutect2, varscan2
- AHNAK | c.16084G>A p.D5362N | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57211753; called by muse, mutect2, varscan2
- AHNAK | c.15154G>C p.D5052H | Missense Mutation (SNP) | VAF 184/551 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57211765; called by muse, mutect2, varscan2
- AHR | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as COSV54123161; called by muse, mutect2, varscan2
- AKAP11 | c.5260del p.H1754Ifs*2 | Frame Shift Del (DEL) | VAF 58/267 reads (22%) | catalogued as COSV50296186; called by mutect2, pindel, varscan2
- AKAP9 | c.4353G>C p.M1451I | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100661856; called by muse, mutect2
- ALG13 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.018); catalogued as COSV52644476, COSV99321525; called by muse, mutect2
- ANGPT4 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs150174277, COSV67921961; called by muse, varscan2
- ANK3 | c.10771G>A p.E3591K | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV55055304; called by muse, mutect2, varscan2
- ANKIB1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as COSV56060855; called by muse, mutect2, varscan2
- ANKRD24 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.044); catalogued as COSV53669868; called by muse, mutect2, varscan2
- ANKRD50 | c.4071G>C p.K1357N | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV72385448; called by muse, mutect2, varscan2
- ANXA7 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV65823378; called by muse, varscan2
- ANXA7 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as rs1564530369, COSV65823397; called by muse, varscan2
- AP5Z1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1254332461, COSV62243327; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.323G>C p.G108A | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.03); catalogued as COSV57340187; called by muse, mutect2, varscan2
- ARHGAP45 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57431346; called by muse, mutect2, varscan2
- ARHGEF18 | c.1333C>A p.L445M (on ENST00000359920 / NM_001130955.2; = p.L341M on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.796); catalogued as rs1167598562, COSV60469249; called by muse, mutect2, varscan2
- ARID1A | c.1901C>G p.S634* | Nonsense Mutation (SNP) | VAF 70/141 reads (50%) | catalogued as COSV61385759; called by muse, mutect2, varscan2
- ARIH2 | c.877del p.H293Tfs*35 | Frame Shift Del (DEL) | VAF 25/132 reads (19%) | catalogued as COSV100711378, COSV62704520, COSV62706443, COSV62706552; called by mutect2, pindel, varscan2
- ARL15 | c.359G>C p.R120T | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV72290337; called by muse, mutect2, varscan2
- ARMC3 | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV53060445; called by muse, mutect2, varscan2
- ARMCX1 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 136/185 reads (74%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV65705098; called by muse, mutect2, varscan2
- ASTL | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 43/139 reads (31%) | catalogued as COSV100668243; called by muse, mutect2, varscan2
- ASXL3 | c.5177C>G p.A1726G | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs369543627, COSV99327034; called by muse, mutect2, varscan2
- ATAD2 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as rs1300574074, COSV99783984; called by muse, mutect2, varscan2
- ATP8B2 | c.2555T>C p.V852A (on ENST00000672630; = p.V819A on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 159/240 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1308529203, COSV59245780; called by muse, mutect2, varscan2
- AXDND1 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.257); catalogued as COSV62641899; called by muse, mutect2, varscan2
- B4GALNT2 | c.1351C>T p.H451Y | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as COSV55925795; called by muse, mutect2, varscan2
- BBOX1 | c.461G>C p.G154A | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV54190734, COSV99589443; called by muse, mutect2, varscan2
- BCL11A | c.755A>G p.E252G (on ENST00000335712 / NM_001365609.1; = p.E286G on NM_018014.4) | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV59628838; called by muse, mutect2, varscan2
- BMPR2 | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 148/227 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs757981921, COSV65808936; called by muse, mutect2, varscan2
- BORA | c.1905G>C p.*635Yext*9 (on ENST00000613797; = p.*560Yext*9 on NM_024808.5 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 41/139 reads (29%) | catalogued as COSV100899820; called by muse, mutect2, varscan2
- BRD2 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV100875883, COSV66373066; called by muse, mutect2, varscan2
- BSND | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV64870581; called by muse, mutect2, varscan2
- BUB1 | c.2728G>T p.D910Y | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV57063161; called by muse, mutect2, varscan2
- C16orf70 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 95/172 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54626999; called by muse, mutect2, varscan2
- C19orf53 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV55605858; called by muse, mutect2, varscan2
- C1QTNF1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546733985, COSV59261657; called by muse, mutect2, varscan2
- CACNA2D1 | c.3055G>A p.E1019K (on ENST00000356253 / NM_001366867.1; = p.E1007K on NM_000722.4) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV62378207; called by muse, mutect2, varscan2
- CACNA2D4 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.739); catalogued as COSV54949085; called by muse, mutect2, varscan2
- CALCR | c.1237G>C p.E413Q (on ENST00000649521 / NM_001164737.2; = p.E397Q on NM_001742.4) | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV64007683; called by muse, mutect2, varscan2
- CAPS2 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs556740394, COSV60824835; called by muse, mutect2, varscan2
- CASZ1 | c.2281G>A p.G761R | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.014); catalogued as COSV59734784; called by muse, mutect2, varscan2
- CBX5 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 98/295 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV52936600; called by muse, mutect2, varscan2
- CCDC148 | c.718C>G p.Q240E | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.059); catalogued as COSV51759180; called by muse, mutect2, varscan2
- CCDC150 | c.1152G>C p.M384I | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.153); catalogued as COSV55872438, COSV55873825; called by muse, mutect2, varscan2
- CCDC186 | c.224G>C p.G75A | Missense Mutation (SNP) | VAF 61/100 reads (61%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.127); catalogued as COSV65159475; called by muse, mutect2, varscan2
- CCDC82 | c.1397G>C p.R466T | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV53593173; called by muse, mutect2, varscan2
- CCDC92 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.998); catalogued as COSV53019546, COSV53020452; called by muse, mutect2, varscan2
- CD209 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV52652662; called by muse, varscan2
- CD209 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 114/370 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.706); catalogued as COSV52652694; called by muse, varscan2
- CD209 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52652727; called by muse, mutect2, varscan2
- CD300LD | c.40+3G>C | Splice Region (SNP) | VAF 34/106 reads (32%) | catalogued as COSV60083650; called by muse, mutect2
- CDH23 | c.933C>G p.I311M | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.747); catalogued as COSV54932018; called by muse, mutect2, varscan2
- CDH7 | c.2107G>C p.D703H | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59885149; called by muse, mutect2, varscan2
- CDK17 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV54128594; called by muse, mutect2, varscan2
- CELF3 | c.1121G>C p.R374T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99309979; called by muse, mutect2
- CERS5 | c.870C>T p.F290= | Splice Region (SNP) | VAF 36/143 reads (25%) | catalogued as rs776073108, COSV58188966; called by muse, mutect2, varscan2
- CFTR | c.3764C>T p.S1255L | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs76649725, CM920186, CM980356, COSV50044366, COSV50049297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CGNL1 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1045864659, COSV55566896; called by muse, mutect2, varscan2
- CHD7 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs763637398, COSV71109613; called by muse, mutect2, varscan2
- CKB | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as COSV100818952, COSV62379479; called by muse, mutect2, varscan2
- CLCN6 | c.1251C>G p.V417= | Splice Region (SNP) | VAF 20/119 reads (17%) | catalogued as COSV56739751; called by muse, mutect2, varscan2
- CLEC4D | c.385-1G>C p.X129_splice | Splice Site (SNP) | VAF 32/72 reads (44%) | catalogued as COSV55228794; called by muse, varscan2
- CLEC4D | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV55228806; called by muse, varscan2
- CMSS1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV70436282; called by muse, mutect2, varscan2
- CMYA5 | c.3640C>T p.Q1214* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs779531611, COSV101483778; called by muse, mutect2, varscan2
- CNNM2 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV63995826; called by muse, mutect2, varscan2
- CNNM4 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.271); catalogued as COSV65660697; called by muse, mutect2, varscan2
- COBL | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV54344082; called by muse, mutect2, varscan2
- COL6A5 | c.7078G>C p.D2360H (on ENST00000312481; = p.D2356H on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55199784; called by muse, mutect2, varscan2
- COQ8A | c.854-1G>C p.X285_splice | Splice Site (SNP) | VAF 25/119 reads (21%) | catalogued as COSV64657229; called by muse, mutect2, varscan2
- DBN1 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 86/215 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV52789232; called by muse, mutect2, varscan2
- DCLRE1B | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV65812637; called by muse, mutect2, varscan2
- DDB1 | c.1407C>G p.I469M | Missense Mutation (SNP) | VAF 131/408 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV57102454; called by muse, mutect2, varscan2
- DEGS1 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV60379114; called by muse, varscan2
- DEPDC5 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV56696222; called by muse, mutect2, varscan2
- DHX57 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537520504, COSV54884641; called by muse, mutect2, varscan2
- DISP2 | c.2472C>G p.F824L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51120199; called by muse, varscan2
- DNAH10 | c.6785T>C p.M2262T (on ENST00000409039; = p.M2201T on NM_207437.3) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68990355, COSV68992447; called by muse, mutect2, varscan2
- DNAH2 | c.3015G>C p.E1005D | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as COSV66718832; called by muse, mutect2, varscan2
- DNAH7 | c.8977C>A p.P2993T | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241532915, COSV56754782, COSV56762117, COSV56772823; called by muse, mutect2, varscan2
- DNAJC13 | c.5041G>A p.D1681N | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.023); catalogued as COSV53449555; called by muse, varscan2
- DNAJC13 | c.5113G>C p.E1705Q | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV53449561; called by muse, varscan2
- DNM2 | c.654_659del p.D218_L220delinsE | In Frame Del (DEL) | VAF 25/89 reads (28%) | catalogued as COSV58960535; called by mutect2, pindel, varscan2
- DOCK6 | c.5287G>A p.D1763N | Missense Mutation (SNP) | VAF 104/254 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV53913814; called by muse, mutect2, varscan2
- DOCK6 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as rs1158387780, COSV99624540; called by muse, mutect2, varscan2
- DOP1A | c.2849C>T p.S950F | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV52709497; called by muse, mutect2, varscan2
- DPY19L4 | c.860A>T p.Q287L | Missense Mutation (SNP) | VAF 84/172 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV68962748; called by muse, mutect2, varscan2
- DVL1 | c.1240G>A p.D414N (on ENST00000378888 / NM_001330311.2; = p.D389N on NM_004421.3) | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs746424149, COSV59563100; called by muse, mutect2, varscan2
- E2F2 | c.579-1G>A p.X193_splice | Splice Site (SNP) | VAF 8/41 reads (20%) | catalogued as rs1372072314, COSV62276413; called by muse, mutect2, varscan2
- ECPAS | c.3475del p.Q1159Kfs*20 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | catalogued as COSV52196105; called by mutect2, pindel, varscan2
- ECT2L | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1159979935, COSV62884096; called by muse, mutect2, varscan2
- EGF | c.3488G>A p.R1163Q | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs201803207; called by muse, mutect2, varscan2
- EIF3K | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 124/301 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50263967; called by muse, mutect2, varscan2
- ELF3 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755079997, COSV62838097; called by muse, mutect2, varscan2
- ELP4 | c.1144G>C p.E382Q (on ENST00000350638; = p.E381Q on NM_019040.5) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63352126; called by muse, mutect2, varscan2
- ENAM | c.1465G>T p.D489Y | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV68535798; called by muse, mutect2, varscan2
- EP300 | c.3244C>T p.Q1082* | Nonsense Mutation (SNP) | VAF 156/242 reads (64%) | catalogued as COSV54332154; called by muse, mutect2, varscan2
- EPB41L2 | c.2079G>C p.K693N | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100440529, COSV61354917, COSV61355616; called by muse, mutect2, varscan2
- EPHA3 | c.2728A>T p.I910F | Missense Mutation (SNP) | VAF 113/269 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60703112; called by muse, mutect2, varscan2
- ERH | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.519); catalogued as COSV53680508; called by muse, mutect2, varscan2
- EVI5 | c.2329G>C p.E777Q | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); catalogued as COSV64826726; called by muse, mutect2, varscan2
- FAM71A | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs947536416, COSV54235425; called by muse, mutect2, varscan2
- FAM90A1 | c.1217C>G p.S406C | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV56711730; called by muse, mutect2, varscan2
- FANCM | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 75/141 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs765686151, COSV57500301; called by muse, mutect2, varscan2
- FBXO27 | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1241716944, COSV53072305, COSV53072898; called by muse, mutect2, varscan2
- FBXO28 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); catalogued as COSV64800238; called by mutect2, varscan2
- FBXW7 | c.1408C>T p.H470Y (on ENST00000281708 / NM_001349798.2; = p.H390Y on NM_018315.5) | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.837); catalogued as rs1169241042, COSV55911610; called by muse, mutect2, varscan2
- FCRL6 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0.03); catalogued as COSV58940958; called by muse, mutect2, varscan2
- FES | c.2059C>T p.R687W | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777821171, COSV60997911; called by muse, mutect2, varscan2
- FGA | c.2025C>G p.I675M | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57393604, COSV57395294; called by muse, mutect2, varscan2
- FHDC1 | c.2943C>G p.F981L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749594434, COSV52599363; called by muse, mutect2, varscan2
- FLNA | c.6937G>T p.E2313* (on ENST00000369850 / NM_001110556.2; = p.E2305* on NM_001456.3) | Nonsense Mutation (SNP) | VAF 27/39 reads (69%) | catalogued as COSV61038696; called by muse, mutect2, varscan2
- FOXM1 | c.2084C>T p.S695L | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.169); catalogued as COSV61205837; called by muse, mutect2, varscan2
- FOXN3 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.428); catalogued as COSV54307908; called by muse, mutect2, varscan2
- FREM2 | c.2303C>T p.S768L | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV54835408, COSV54835825; called by muse, mutect2, varscan2
- FRMPD1 | c.3110C>T p.S1037F | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.28); catalogued as COSV66700159, COSV66700293; called by muse, mutect2, varscan2
- FRY | c.7207C>G p.L2403V | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as COSV100969538, COSV66569214; called by muse, mutect2, varscan2
- FRYL | c.8641G>A p.E2881K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.468); catalogued as rs867610050, COSV51945574; called by muse, mutect2, varscan2
- FSCN1 | c.853C>G p.Q285E | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61017163, COSV61017445; called by muse, mutect2, varscan2
- GALNT15 | c.1231C>A p.P411T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1304177511, COSV60216679; called by muse, mutect2, varscan2
- GALR2 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160692852, COSV57162332; called by muse, mutect2, varscan2
- GARS1 | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 109/321 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV66828267; called by muse, mutect2, varscan2
- GFRA2 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.873); catalogued as COSV100151347; called by muse, mutect2
- GNA12 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1358616075, COSV99282264; called by muse, mutect2, varscan2
- GNE | c.818C>T p.S273L (on ENST00000396594 / NM_001128227.3; = p.S242L on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as rs771167726, COSV64951734; called by muse, mutect2, varscan2
- GOLGA3 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV52629801; called by muse, mutect2, varscan2
- GOLGA6B | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 39/331 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs746249202, COSV101406894; called by muse, mutect2, varscan2
- GPR12 | c.503C>A p.S168Y | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1263999705, COSV67344296; called by muse, mutect2, varscan2
- GPS1 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 40/108 reads (37%) | catalogued as COSV100135801; called by muse, mutect2, varscan2
- GSPT2 | c.1876G>C p.E626Q | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV100468033, COSV61214173; called by muse, mutect2, varscan2
- HARS1 | c.899G>C p.G300A | Missense Mutation (SNP) | VAF 156/412 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.146); catalogued as COSV56906596; called by muse, mutect2, varscan2
- HDLBP | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.42); PolyPhen benign (0.149); catalogued as COSV60494725; called by muse, mutect2, varscan2
- HIVEP3 | c.5128G>C p.E1710Q | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV56014324; called by muse, mutect2, varscan2
- HLA-B | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs137854653, CM1412111, COSV69520364, COSV69521019; called by muse, mutect2, varscan2
- HNF1A | c.657G>C p.E219D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as COSV57461658; called by muse, mutect2, varscan2
- HOXB6 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 114/344 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV53312531; called by muse, varscan2
- HSPB9 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs1183490128, COSV56790479; called by muse, mutect2, varscan2
- HTATSF1 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 51/64 reads (80%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54478465, COSV54479255; called by muse, mutect2, varscan2
- IBTK | c.1645G>C p.E549Q | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.1); catalogued as COSV60392494; called by muse, mutect2, varscan2
- IFNK | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as COSV51779544; called by muse, mutect2, varscan2
- IGKV1-16 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 163/473 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs557188901; called by muse, mutect2, varscan2
- IGKV1-9 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs756494691; called by muse, mutect2, varscan2
- IKZF2 | c.461A>G p.N154S | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV59578243; called by muse, mutect2, varscan2
- IL31RA | c.1007C>A p.S336Y | Missense Mutation (SNP) | VAF 83/222 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV51681363; called by muse, mutect2, varscan2
- IL6 | c.402G>C p.E134D | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.798); catalogued as COSV51732613; called by muse, mutect2, varscan2
- IMMT | c.2014C>G p.Q672E | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.065); catalogued as COSV54479793; called by muse, mutect2, varscan2
- INPPL1 | c.2434G>C p.D812H | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV53355033; called by muse, mutect2, varscan2
- ITGA8 | c.528G>C p.Q176H | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV65227946; called by muse, mutect2, varscan2
- ITGB3BP | c.375C>G p.I125M | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV52132522; called by muse, mutect2, varscan2
- ITIH4 | c.2163G>A p.M721I | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1352097304, COSV56573515; called by muse, mutect2, varscan2
- JAKMIP2 | c.2318G>C p.R773T | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54602797; called by muse, mutect2, varscan2
- JMJD1C | c.1444G>T p.E482* | Nonsense Mutation (SNP) | VAF 85/227 reads (37%) | catalogued as COSV101232144, COSV67861284; called by muse, mutect2, varscan2
- KAT6A | c.4339G>A p.E1447K | Missense Mutation (SNP) | VAF 69/119 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.684); catalogued as COSV55905488; called by muse, mutect2, varscan2
- KCND3 | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.145); catalogued as CM1212995, COSV56179879; called by muse, mutect2, varscan2
- KCNMB4 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 81/299 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as COSV50691224; called by muse, mutect2, varscan2
- KDM3B | c.2032C>T p.H678Y | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); catalogued as COSV58690061, COSV58692292; called by muse, mutect2, varscan2
- KDM5A | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV66992004; called by muse, mutect2, varscan2
- KDM8 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 71/121 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0.084); catalogued as COSV53729439; called by muse, mutect2, varscan2
- KIAA0319L | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs1424185070, COSV100357507, COSV57845208; called by muse, mutect2, varscan2
- KIF1A | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV57487471; called by muse, mutect2, varscan2
- KIF21A | c.3518C>G p.S1173* (on ENST00000361418 / NM_001378440.1; = p.S1160* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 60/177 reads (34%) | catalogued as COSV100735254; called by muse, mutect2, varscan2
- KMT2E | c.3908C>G p.S1303* | Nonsense Mutation (SNP) | VAF 64/175 reads (37%) | catalogued as COSV99995711; called by muse, mutect2, varscan2
- KRT6A | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 118/324 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58104828; called by muse, mutect2, varscan2
- LAMA1 | c.5441G>C p.R1814T | Missense Mutation (SNP) | VAF 82/227 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV101055600, COSV67536004; called by muse, mutect2, varscan2
- LATS1 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 118/336 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.17); catalogued as COSV53589978; called by muse, varscan2
- LATS1 | c.1385C>G p.S462* | Nonsense Mutation (SNP) | VAF 128/385 reads (33%) | catalogued as COSV99485150; called by muse, varscan2
- LGI3 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV60443259; called by muse, mutect2, varscan2
- LIPT1 | c.223G>C p.G75R | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60739602; called by muse, mutect2, varscan2
- LPAR6 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 101/193 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as rs767102500, COSV57304894; called by muse, mutect2, varscan2
- LRP1B | c.9334G>A p.E3112K | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1257819931, COSV101258381, COSV67211217; called by muse, mutect2, varscan2
- LRRC10 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 38/384 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs138855649; called by muse, mutect2
- LRRC55 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV73006482; called by muse, mutect2, varscan2
- LRTM2 | c.1023G>T p.K341N | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1390028417, COSV54564737, COSV54566144; called by muse, mutect2, varscan2
- LTA | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.998); catalogued as COSV69304518; called by muse, mutect2, varscan2
- LYG2 | c.530C>G p.S177* | Nonsense Mutation (SNP) | VAF 89/265 reads (34%) | catalogued as rs1272979120, COSV100283489; called by muse, mutect2, varscan2
- MANEA | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs1161923022, COSV62589582; called by muse, mutect2, varscan2
- MAP7 | c.251G>C p.R84T | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs763172340, COSV63419135; called by muse, mutect2, varscan2
- MAPT | c.1832C>A p.P611H (on ENST00000262410 / NM_001377265.1; = p.P219H on NM_005910.5) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1162732433, COSV52239728; called by muse, mutect2, varscan2
- MBD1 | c.1588G>A p.V530I (on ENST00000269468 / NM_001323950.1; = p.V428I on NM_002384.2) | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV54000777; called by muse, mutect2, varscan2
- MBD1 | c.1447G>T p.E483* (on ENST00000269468 / NM_001323950.1; = p.E427* on NM_015844.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/119 reads (32%) | catalogued as COSV99495349; called by muse, mutect2, varscan2
- MCC | c.2340G>C p.K780N | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56728001; called by muse, mutect2, varscan2
- MCMBP | c.1600G>C p.E534Q | Missense Mutation (SNP) | VAF 57/85 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV63509062; called by muse, mutect2, varscan2
- METTL3 | c.1594G>C p.E532Q | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52968547, COSV52970549; called by muse, mutect2, varscan2
- MIB1 | c.678C>G p.F226L | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.481); catalogued as COSV55089939; called by muse, mutect2, varscan2
- MINDY3 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as COSV53219996; called by muse, mutect2, varscan2
- MROH9 | c.617-1G>C p.X206_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | catalogued as COSV63010976; called by muse, varscan2
- MTMR4 | c.2773C>T p.R925W | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs572156303, COSV60200410; called by muse, mutect2, varscan2
- MX1 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 97/374 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55818932; called by muse, mutect2, varscan2
- MYH6 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 143/346 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV62449777, COSV62453954; called by muse, mutect2, varscan2
- MYLK3 | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1424060095, COSV67363877; called by muse, mutect2, varscan2
- MYO3A | c.2501G>C p.G834A | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1459076412, COSV56328497; called by muse, mutect2, varscan2
- NCAM1 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57515205; called by muse, mutect2
- NDUFAF5 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1331491109, COSV52518724, COSV52520534; called by muse, mutect2, varscan2
- NEK4 | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51780149; called by muse, mutect2, varscan2
- NELFE | c.1009G>C p.D337H | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV64887629; called by muse, mutect2, varscan2
- NELFE | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 77/210 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.161); catalogued as COSV64811362; called by muse, mutect2, varscan2
- NFATC2 | c.2379G>C p.Q793H | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs768990056, COSV65355374; called by muse, mutect2, varscan2
- NGLY1 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 54/134 reads (40%) | catalogued as COSV99770015; called by muse, mutect2, varscan2
- NIN | c.5920C>G p.H1974D (on ENST00000382041 / NM_182946.1; = p.H1261D on NM_016350.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs1193155606, COSV99811354; called by muse, mutect2
- NME9 | c.199G>A p.E67K (on ENST00000333911 / NM_001349024.2; = p.E45K on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV58618127; called by muse, mutect2, varscan2
- NOP56 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as COSV61389771; called by muse, mutect2, varscan2
- NRAP | c.1179C>G p.F393L | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV63489972; called by muse, mutect2, varscan2
- NRCAM | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61030439, COSV61035172; called by muse, mutect2, varscan2
- NRXN3 | c.1370A>G p.Y457C (on ENST00000335750 / NM_001330195.2; = p.Y84C on NM_004796.6) | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59718524, COSV59742093; called by muse, mutect2, varscan2
- NYNRIN | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV66842149; called by muse, mutect2, varscan2
- NYNRIN | c.4268C>T p.S1423F | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); catalogued as COSV66842153; called by muse, mutect2, varscan2
- OARD1 | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as COSV55107616; called by muse, mutect2, varscan2
- OBSCN | c.10192G>C p.E3398Q | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as COSV52768386; called by muse, mutect2, varscan2
- OCA2 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV62344086; called by muse, mutect2, varscan2
- OR1M1 | c.920G>T p.R307I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as rs1475710581, COSV101447532, COSV70037474; called by muse, mutect2, varscan2
- OSBPL3 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 93/247 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV57655813; called by muse, mutect2, varscan2
- PALLD | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54979365; called by muse, mutect2, varscan2
- PAPPA2 | c.3392G>C p.G1131A | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.677); catalogued as COSV62796240; called by muse, mutect2
- PCDHA12 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56496152; called by muse, mutect2, varscan2
- PCDHGA11 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.124); catalogued as COSV53935531; called by muse, mutect2, varscan2
- PCK2 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53748624; called by muse, mutect2, varscan2
- PCNX2 | c.2836C>G p.L946V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); catalogued as rs1371810821, COSV50796385; called by muse, mutect2, varscan2
- PDS5B | c.2749C>G p.Q917E | Missense Mutation (SNP) | VAF 122/238 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.227); catalogued as COSV59726346; called by muse, mutect2, varscan2
- PEG3 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV55631627; called by muse, mutect2, varscan2
- PHLDB2 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as COSV101208380; called by muse, mutect2, varscan2
- PIGC | c.486C>G p.I162M | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs998126777, COSV51129788; called by muse, mutect2, varscan2
- PIK3IP1 | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53223442, COSV53223515; called by muse, mutect2, varscan2
- PIKFYVE | c.5773C>G p.Q1925E | Missense Mutation (SNP) | VAF 71/115 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100011103, COSV52240233; called by muse, mutect2, varscan2
- PIWIL3 | c.817C>G p.Q273E | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as rs1390822354, COSV59995026; called by muse, mutect2, varscan2
- PLEKHA8 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV51650185, COSV51650625; called by muse, mutect2, varscan2
- PLEKHG2 | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV99216732, COSV99217741; called by muse, mutect2
- PNPLA3 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1233022871, COSV53378073; called by muse, mutect2, varscan2
- PNPLA6 | c.2726G>A p.R909Q (on ENST00000414982 / NM_001166111.2; = p.R861Q on NM_006702.5) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1396289067, COSV55377322; called by muse, mutect2, varscan2
- POLI | c.2187G>T p.K729N | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs1250101129, COSV54188907; called by muse, mutect2, varscan2
- POM121L12 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 19/38 reads (50%) | catalogued as COSV101374831; called by muse, mutect2, varscan2
- PPFIBP1 | c.537G>C p.L179F | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57290563; called by muse, mutect2, varscan2
- PPP1R12A | c.1670G>A p.R557K | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.899); catalogued as COSV54107781; called by muse, mutect2, varscan2
- PPP1R3A | c.2546C>A p.S849* | Nonsense Mutation (SNP) | VAF 77/193 reads (40%) | catalogued as COSV99491828; called by muse, mutect2, varscan2
- PPP2R3B | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs371032589, COSV66813178; called by muse, mutect2, varscan2
- PSD3 | c.676C>G p.Q226E | Missense Mutation (SNP) | VAF 69/123 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as COSV100497133, COSV58967511; called by muse, mutect2, varscan2
- PSD3 | c.305C>G p.S102C | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV58967518; called by muse, mutect2, varscan2
- PSMA1 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.775); catalogued as rs759228621, COSV67165897; called by muse, mutect2, varscan2
- PUM1 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 60/224 reads (27%) | catalogued as COSV99927426, COSV99927565; called by muse, varscan2
- PZP | c.2817G>C p.L939F | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54359065; called by muse, mutect2, varscan2
- QPCTL | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs758628165, COSV50003759; called by muse, mutect2, varscan2
- RAB10 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53089440; called by muse, mutect2, varscan2
- RAD21 | c.1117T>C p.F373L | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.931); catalogued as COSV52058491; called by muse, mutect2, varscan2
- RANBP2 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99311163; called by muse, mutect2
- RASGEF1C | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63180140; called by muse, mutect2, varscan2
- RB1 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 37/146 reads (25%) | catalogued as COSV57297220, COSV99922873; called by muse, mutect2, varscan2
- RB1CC1 | c.2366G>A p.G789E | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV50246977; called by muse, mutect2, varscan2
- RBL2 | c.1456+1G>A p.X486_splice | Splice Site (SNP) | VAF 27/40 reads (68%) | catalogued as COSV50875790; called by muse, mutect2, varscan2
- RBL2 | c.1552G>C p.D518H | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751815905, COSV50875812, COSV50879863; called by muse, mutect2, varscan2
- RETREG2 | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 110/181 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV56087450, COSV56089450; called by muse, mutect2, varscan2
- REV3L | c.5011C>T p.Q1671* | Nonsense Mutation (SNP) | VAF 46/131 reads (35%) | catalogued as COSV100724800; called by muse, mutect2, varscan2
- RGS9 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.266); catalogued as COSV52224872, COSV52227480; called by muse, mutect2, varscan2
- RIC1 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52608870; called by muse, mutect2, varscan2
- RNF111 | c.2612C>T p.S871L | Missense Mutation (SNP) | VAF 116/265 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.34); catalogued as COSV62085459; called by muse, mutect2, varscan2
- RNF39 | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.053); catalogued as COSV54993160; called by muse, mutect2, varscan2
- RO60 | c.1139C>G p.S380C | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66473670; called by muse, mutect2, varscan2
- RP1 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as rs756961463, COSV55113657; called by muse, mutect2, varscan2
- RPAP3 | c.546-1G>C p.X182_splice | Splice Site (SNP) | VAF 100/267 reads (37%) | catalogued as COSV50041663; called by muse, mutect2, varscan2
- RPS6KA6 | c.880C>G p.Q294E | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV53119030; called by muse, mutect2, varscan2
- RSPH6A | c.1630C>T p.H544Y | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55571326; called by muse, mutect2, varscan2
- RXFP2 | c.2006-1G>C p.X669_splice | Splice Site (SNP) | VAF 30/90 reads (33%) | catalogued as COSV53635000; called by muse, mutect2, varscan2
- RYR2 | c.2531G>C p.R844T | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.045); catalogued as COSV100769338, COSV63681576; called by muse, mutect2, varscan2
- SAAL1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV55515477; called by muse, mutect2, varscan2
- SCN10A | c.1501C>T p.H501Y | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1453769486, COSV71861121; called by muse, mutect2, varscan2
- SCYL2 | c.2621C>G p.S874C | Missense Mutation (SNP) | VAF 58/240 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV62568545; called by muse, mutect2, varscan2
- SENP6 | c.2702C>G p.S901C | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV64186934; called by muse, mutect2, varscan2
- SFRP2 | c.201G>C p.E67D | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.074); catalogued as COSV56837414; called by muse, mutect2, varscan2
- SFTPA2 | c.140G>C p.R47T | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); catalogued as COSV64882403; called by muse, mutect2, varscan2
- SKOR1 | c.2877C>G p.F959L | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV58245453; called by muse, mutect2, varscan2
- SLC16A7 | c.311C>A p.S104Y | Missense Mutation (SNP) | VAF 119/317 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53894014, COSV53895652; called by muse, mutect2, varscan2
- SLC29A4 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs1434801405, COSV51873853; called by muse, mutect2, varscan2
- SLC35C2 | c.177C>G p.F59L | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54756774; called by muse, mutect2, varscan2
- SLC4A11 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.479); catalogued as rs772271724, COSV101196101, COSV66261620; called by muse, mutect2, varscan2
- SLC8A3 | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 105/274 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV63520732, COSV63524800; called by muse, mutect2, varscan2
- SLCO1B3 | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53936574; called by muse, mutect2, varscan2
- SMCR8 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs780272538, COSV58176957; called by muse, mutect2, varscan2
- SMG8 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as COSV56284976; called by muse, mutect2, varscan2
- SNX29 | c.1379C>T p.S460L | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1170452948, COSV60062060; called by muse, mutect2, varscan2
- SOX10 | c.1334C>G p.S445* | Nonsense Mutation (SNP) | VAF 23/39 reads (59%) | catalogued as COSV100704004; called by muse, mutect2, varscan2
- SPRY2 | c.662G>A p.C221Y | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV65701380; called by muse, mutect2, varscan2
- ST18 | c.3028G>A p.E1010K | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52492134; called by muse, mutect2, varscan2
- STAB1 | c.6259C>T p.R2087C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as COSV58735381; called by muse, mutect2, varscan2
- STAC | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 82/238 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs199662305, COSV56209760, COSV56209987; called by muse, mutect2, varscan2
- STAT4 | c.1235G>C p.G412A | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61829402; called by muse, mutect2, varscan2
- STEAP4 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57329100; called by muse, mutect2, varscan2
- STK11IP | c.2822C>T p.S941F | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1481027258, COSV55248160; called by muse, mutect2, varscan2
- STK3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); catalogued as rs1202010149, COSV69223186; called by muse, mutect2, varscan2
- STK35 | c.1564G>C p.E522Q | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.326); catalogued as COSV55690372; called by muse, mutect2, varscan2
- SVIL | c.1939G>C p.E647Q | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV63442790; called by muse, mutect2, varscan2
- SYNJ1 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59147504; called by muse, mutect2, varscan2
- SYT11 | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64174113; called by muse, mutect2, varscan2
- TAFA4 | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as COSV55136927; called by muse, mutect2, varscan2
- TBC1D22B | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV65142721; called by muse, mutect2, varscan2
- TET3 | c.1023G>C p.Q341H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV59880777; called by muse, mutect2, varscan2
- TGM5 | c.437-1G>C p.X146_splice (on ENST00000220420 / NM_201631.4; = p.X64_splice on NM_004245.4) | Splice Site (SNP) | VAF 43/181 reads (24%) | catalogued as COSV55009859; called by muse, mutect2, varscan2
- THBS4 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369507698, COSV63469127; called by muse, mutect2, varscan2
- THG1L | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV51452750; called by muse, mutect2, varscan2
- THSD7B | c.4168G>C p.D1390H (on ENST00000272643; = p.D1388H on NM_001316349.2) | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV55680200, COSV99754340; called by muse, mutect2, varscan2
- TIMP4 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV55139015; called by muse, mutect2, varscan2
- TLR3 | c.184C>G p.Q62E | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV57168252; called by muse, mutect2, varscan2
- TM4SF18 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs201899022; called by muse, mutect2, varscan2
- TMEM164 | c.882G>C p.K294N (on ENST00000372068 / NM_032227.4; = p.K145N on NM_017698.2) | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55811936; called by muse, mutect2, varscan2
- TNIK | c.2258G>A p.G753E | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52672686; called by muse, mutect2, varscan2
- TNKS | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 86/160 reads (54%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1163830480, COSV60056324; called by muse, varscan2
- TOP3A | c.1458G>C p.W486C | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285538297, COSV58176952; called by muse, varscan2
- TOR1AIP1 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54869289; called by muse, mutect2, varscan2
- TOX3 | c.741G>C p.K247N | Missense Mutation (SNP) | VAF 32/474 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54866035; called by muse, mutect2
- TPBG | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs201739068, COSV100869734; called by muse, varscan2
- TPH1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 123/348 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51457926; called by muse, mutect2, varscan2
- TPP2 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.877); catalogued as COSV65752317; called by muse, mutect2, varscan2
- TRIM27 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.311); catalogued as COSV65873500; called by muse, mutect2, varscan2
- TRIM32 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV57773291; called by muse, mutect2, varscan2
- TRIM4 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62468967; called by muse, mutect2, varscan2
- TRIM9 | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV53616068; called by muse, mutect2, varscan2
- TRPC3 | c.2685G>C p.K895N (on ENST00000379645 / NM_001366479.2; = p.K822N on NM_003305.2) | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); catalogued as COSV53374747; called by muse, mutect2, varscan2
- TSGA10IP | c.1274G>T p.R425I | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1259629090, COSV73245275; called by muse, mutect2, varscan2
- TTC21A | c.3271G>A p.E1091K | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV56187894; called by muse, mutect2, varscan2
- TTN | c.95641C>T p.H31881Y (on ENST00000591111; = p.H24457Y on NM_003319.4) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | PolyPhen benign (0.012); catalogued as COSV60011282; called by muse, mutect2, varscan2
- TTN | c.4812C>T p.I1604= (on ENST00000591111; = p.I1558= on NM_003319.4) | Splice Region (SNP) | VAF 71/212 reads (33%) | catalogued as COSV60011319; called by muse, mutect2, varscan2
- TUBB2A | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 118/349 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV61318922, COSV61319238; called by muse, mutect2, varscan2
- TUBB6 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.113); catalogued as rs940484159, COSV52314076; called by muse, mutect2, varscan2
- UBR4 | c.9937G>A p.E3313K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV64382064; called by muse, mutect2, varscan2
- USP21 | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.968); catalogued as COSV57088385; called by muse, mutect2, varscan2
- USP28 | c.534G>A p.Q178= | Splice Region (SNP) | VAF 32/55 reads (58%) | catalogued as rs34802473, COSV50160447; called by muse, mutect2, varscan2
- VASH1 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.597); catalogued as rs762887343, COSV51335434; called by muse, mutect2, varscan2
- VCAM1 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV54119053; called by muse, mutect2, varscan2
- WASHC4 | c.344G>C p.G115A | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59889340; called by muse, varscan2
- WASHC5 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV59195966; called by muse, mutect2, varscan2
- WDR33 | c.1956C>A p.F652L | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.084); catalogued as COSV59248260; called by muse, mutect2, varscan2
- WDR49 | c.473C>G p.S158C (on ENST00000308378 / NM_001366158.1; = p.S499C on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV57707249; called by muse, mutect2, varscan2
- WDR64 | c.1419C>G p.I473M | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.577); catalogued as COSV63793944, COSV63795219; called by muse, mutect2, varscan2
- WTAP | c.87-1G>C p.X29_splice | Splice Site (SNP) | VAF 33/105 reads (31%) | catalogued as COSV100493348, COSV61610030; called by muse, mutect2, varscan2
- WWC1 | c.1987C>T p.Q663* | Nonsense Mutation (SNP) | VAF 35/89 reads (39%) | catalogued as COSV99514110; called by muse, mutect2, varscan2
- YIPF2 | c.843C>G p.F281L | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53403394; called by muse, mutect2
- YME1L1 | c.1798G>C p.E600Q (on ENST00000326799 / NM_139312.3; = p.E543Q on NM_014263.4) | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58759166; called by muse, mutect2, varscan2
- ZFC3H1 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 114/215 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as rs191798821, COSV66431964; called by muse, mutect2, varscan2
- ZFP37 | c.1675C>T p.H559Y | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as rs1192733252, COSV65286710; called by muse, mutect2, varscan2
- ZNF114 | c.384G>A p.M128I | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV59944178; called by muse, mutect2, varscan2
- ZNF345 | c.382G>C p.G128R | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as COSV59323810, COSV59325519; called by muse, mutect2, varscan2
- ZNF423 | c.3182C>G p.S1061C (on ENST00000563137 / NM_001379286.1; = p.S1053C on NM_015069.4) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV99279527; called by muse, mutect2
- ZNF423 | c.2462G>A p.S821N (on ENST00000563137 / NM_001379286.1; = p.S813N on NM_015069.4) | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as rs748113449, COSV52185967; called by muse, mutect2, varscan2
- ZNF430 | c.569C>G p.S190* | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | catalogued as COSV99841526; called by muse, mutect2, varscan2
- ZNF484 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 92/216 reads (43%) | catalogued as COSV100214428, COSV100214458; called by muse, mutect2, varscan2
- ZNF496 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.229); catalogued as COSV54176440; called by muse, mutect2, varscan2
- ZNF529 | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV61900066; called by muse, mutect2, varscan2
- ZNF608 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV60437299; called by muse, mutect2, varscan2
- ZNF614 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 73/213 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs868492152, COSV54545934; called by muse, mutect2, varscan2
- ZNF667 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV52633543, COSV99410645; called by muse, mutect2, varscan2
- ZNF695 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs1432893129, COSV60585663; called by muse, mutect2
- ALAS1 | c.423del p.E143Rfs*14 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- GPR179 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- KDM6A | c.4190dup p.S1398Ifs*12 | Frame Shift Ins (INS) | VAF 64/116 reads (55%) | called by mutect2, pindel, varscan2
- KIR2DS4 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 134/404 reads (33%) | called by muse, mutect2, varscan2
- SPATA31A3 | c.3855C>G p.I1285M | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by mutect2, varscan2
- TUBGCP5 | c.2317G>C p.D773H | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- AC005833.1 | c.1599G>A p.K533= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as rs1265913881, COSV52896939; called by muse, mutect2, varscan2
- ACOXL | c.474C>T p.F158= | Silent (SNP) | VAF 74/193 reads (38%) | catalogued as COSV61324198; called by muse, mutect2, varscan2
- AGXT2 | c.1350G>A p.R450= | Silent (SNP) | VAF 56/142 reads (39%) | catalogued as COSV51485823; called by muse, mutect2, varscan2
- AHNAK | c.16383G>C p.V5461= | Silent (SNP) | VAF 80/182 reads (44%) | catalogued as COSV57211739; called by muse, mutect2, varscan2
- AL592490.1 | c.1026C>G p.V342= | Silent (SNP) | VAF 82/187 reads (44%) | catalogued as COSV69425923; called by muse, mutect2, varscan2
- ANKRD30A | c.1824G>C p.L608= (on ENST00000611781; = p.L552= on NM_052997.2) | Silent (SNP) | VAF 63/186 reads (34%) | catalogued as COSV64609061; called by muse, mutect2, varscan2
- ARHGAP9 | c.2220G>A p.L740= (on ENST00000393797 / NM_001319850.2; = p.L721= on NM_032496.4) | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as COSV57361049; called by muse, mutect2, varscan2
- ARHGEF4 | c.1395C>T p.I465= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV58121503; called by muse, mutect2, varscan2
- ARID2 | c.1062G>C p.L354= | Silent (SNP) | VAF 76/235 reads (32%) | catalogued as rs943710368, COSV57601491, COSV57602295; called by muse, mutect2, varscan2
- ASPSCR1 | c.324C>T p.F108= | Silent (SNP) | VAF 50/116 reads (43%) | catalogued as COSV60728420; called by muse, mutect2, varscan2
- ATP7A | c.4248G>A p.E1416= | Silent (SNP) | VAF 120/171 reads (70%) | catalogued as COSV100430067, COSV58445432; called by muse, mutect2, varscan2
- BAHD1 | c.1956C>G p.L652= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV69083872; called by muse, mutect2, varscan2
- C10orf120 | c.600G>A p.L200= | Silent (SNP) | VAF 50/78 reads (64%) | catalogued as rs781314088, COSV61491859; called by muse, varscan2
- C1orf112 | c.159G>A p.R53= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV53678248, COSV53684119; called by muse, mutect2, varscan2
- CACNA1E | c.5118C>T p.F1706= | Silent (SNP) | VAF 59/136 reads (43%) | catalogued as COSV62391735, COSV62406527; called by muse, mutect2, varscan2
- CACNA1E | c.6798C>T p.I2266= (on ENST00000367573 / NM_001205293.3; = p.I2223= on NM_000721.4) | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs750465912, COSV62426471; called by muse, mutect2, varscan2
- CASD1 | c.1431A>G p.S477= | Silent (SNP) | VAF 50/154 reads (32%) | catalogued as COSV51972088; called by muse, mutect2, varscan2
- CD209 | c.1068C>T p.C356= | Silent (SNP) | VAF 137/413 reads (33%) | catalogued as rs749655694, COSV52652610; called by muse, mutect2, varscan2
- CDKAL1 | c.630C>T p.I210= | Silent (SNP) | VAF 47/152 reads (31%) | catalogued as rs759229185, COSV51182602; called by muse, mutect2, varscan2
- CEP170B | c.2244C>T p.L748= (on ENST00000453495; = p.L677= on NM_015005.3) | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV101371377; called by muse, mutect2
- CNN3 | c.222C>T p.N74= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as rs374270794; called by muse, mutect2, varscan2
- CNTROB | c.36C>T p.L12= | Silent (SNP) | VAF 69/181 reads (38%) | catalogued as rs1188050437, COSV58050153; called by muse, mutect2, varscan2
- COL4A6 | c.2100G>T p.G700= | Silent (SNP) | VAF 56/71 reads (79%) | catalogued as COSV57864571; called by muse, mutect2, varscan2
- CPB2 | c.765G>A p.L255= | Silent (SNP) | VAF 79/161 reads (49%) | catalogued as COSV51673737; called by muse, mutect2, varscan2
- CRNKL1 | c.2331C>G p.L777= | Silent (SNP) | VAF 111/323 reads (34%) | catalogued as COSV58548425; called by muse, mutect2, varscan2
- DDX51 | c.1605C>T p.F535= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs748487633, COSV57958024; called by muse, mutect2, varscan2
- DEPP1 | c.567C>T p.S189= | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as COSV53573960; called by muse, mutect2, varscan2
- DGLUCY | c.1017C>T p.F339= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as COSV56365977; called by muse, mutect2, varscan2
- DISP2 | c.2412C>T p.S804= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as rs1487339524, COSV51120148; called by muse, varscan2
- DNAH5 | c.5790G>A p.K1930= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV54220366; called by muse, mutect2, varscan2
- DNAH9 | c.5271C>G p.L1757= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as COSV52346673; called by muse, mutect2, varscan2
- DOCK2 | c.1977C>T p.I659= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as COSV56955246; called by muse, mutect2, varscan2
- DPP10 | c.144C>T p.L48= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as rs1162964373, COSV59682478; called by muse, mutect2, varscan2
- DSC2 | c.1809C>T p.I603= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV51864070; called by muse, mutect2, varscan2
- DVL3 | c.1374C>T p.F458= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV57455826; called by muse, varscan2
- DVL3 | c.1428C>T p.F476= | Silent (SNP) | VAF 67/180 reads (37%) | catalogued as COSV57455837; called by muse, varscan2
- EIF2B5 | c.2034C>T p.F678= (on ENST00000647909; = p.F670= on NM_003907.3) | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV56604397; called by muse, mutect2, varscan2
- EXO5 | c.1083C>G p.L361= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV56415676; called by muse, mutect2, varscan2
- FARSA | c.1278G>A p.L426= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as COSV53366411; called by muse, mutect2, varscan2
- FBN1 | c.6429C>T p.I2143= | Silent (SNP) | VAF 67/137 reads (49%) | catalogued as COSV57315151; called by muse, mutect2, varscan2
- FERMT1 | c.876C>T p.L292= | Silent (SNP) | VAF 61/164 reads (37%) | catalogued as COSV54092620; called by muse, mutect2, varscan2
- FRMPD2 | c.3477C>T p.V1159= | Silent (SNP) | VAF 90/116 reads (78%) | catalogued as COSV59717495; called by muse, mutect2, varscan2
- FSD2 | c.1284C>G p.V428= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV58009677; called by muse, mutect2, varscan2
- GALNT15 | c.1356C>T p.F452= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as COSV60216688, COSV60218586; called by muse, mutect2, varscan2
- GCN1 | c.4317C>G p.L1439= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs1488924250, COSV56107020; called by muse, mutect2, varscan2
- GFM1 | c.474C>A p.V158= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV51832339; called by muse, mutect2, varscan2
- GMEB1 | c.954G>A p.K318= | Silent (SNP) | VAF 75/154 reads (49%) | catalogued as COSV53794161; called by muse, mutect2, varscan2
- GNA15 | c.690C>T p.I230= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV53585919, COSV99505304; called by muse, mutect2, varscan2
- GPR149 | c.369G>A p.A123= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV67666995; called by muse, mutect2, varscan2
- GUCY2C | c.1653G>T p.V551= | Silent (SNP) | VAF 43/138 reads (31%) | catalogued as rs1275284357, COSV53789457; called by muse, mutect2, varscan2
- HELZ | c.2640C>T p.F880= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as COSV62377998; called by muse, mutect2, varscan2
- HID1 | c.279C>T p.I93= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as rs533342753, COSV59351416; called by muse, mutect2, varscan2
- HIP1R | c.603C>T p.I201= | Silent (SNP) | VAF 88/188 reads (47%) | catalogued as rs762232461, COSV53441018; called by muse, mutect2, varscan2
- HUWE1 | c.12063C>G p.V4021= | Silent (SNP) | VAF 28/38 reads (74%) | catalogued as COSV99470458; called by muse, mutect2, varscan2
- ITGA11 | c.702G>A p.Q234= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs1335787969, COSV59877086; called by muse, mutect2, varscan2
- KCNS1 | c.618C>G p.L206= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1396398188, COSV60260010; called by muse, mutect2
- KDM7A | c.1608C>G p.L536= | Silent (SNP) | VAF 79/271 reads (29%) | catalogued as COSV50091056; called by muse, mutect2
- KIR2DL1 | c.486G>A p.R162= | Silent (SNP) | VAF 92/193 reads (48%) | catalogued as COSV52408059; called by muse, mutect2, varscan2
- LIPK | c.492G>A p.K164= | Silent (SNP) | VAF 69/120 reads (58%) | catalogued as COSV68200962; called by muse, mutect2, varscan2
- LTB4R2 | c.1143G>A p.E381= (on ENST00000528054; = p.E350= on NM_019839.5) | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as rs1166382960, COSV51865486; called by muse, mutect2, varscan2
- LUZP2 | c.280C>T p.L94= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as COSV61202547; called by muse, mutect2, varscan2
- MAP2K5 | c.561G>A p.P187= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs746892344, COSV51613634; called by muse, mutect2, varscan2
- MAPK10 | c.141C>T p.V47= (on ENST00000359221 / NM_001351625.2; = p.V85= on NM_002753.5) | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV60381022; called by muse, mutect2, varscan2
- MAPT | c.165A>C p.G55= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV52239714; called by muse, mutect2, varscan2
- MC5R | c.288C>T p.I96= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV61254501; called by muse, mutect2, varscan2
- MC5R | c.570C>T p.L190= | Silent (SNP) | VAF 323/836 reads (39%) | catalogued as rs1021852656, COSV61254506; called by muse, mutect2, varscan2
- MED16 | c.975C>T p.I325= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs913000131, COSV99515072; called by muse, mutect2, varscan2
- MFSD6 | c.1221G>A p.E407= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV55622306; called by muse, mutect2, varscan2
- MR1 | c.12G>A p.L4= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV51580676, COSV99294770; called by muse, mutect2, varscan2
- MTSS2 | c.1779G>A p.V593= | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as COSV55380306; called by muse, mutect2, varscan2
- MYO1C | c.1191C>T p.I397= (on ENST00000648651 / NM_001080779.2; = p.I362= on NM_033375.5) | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV62999038; called by muse, mutect2, varscan2
- NOTCH1 | c.1770C>G p.L590= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs949220276, COSV53046475; called by muse, mutect2, varscan2
- NPAS2 | c.1998C>T p.F666= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV59557284; called by muse, mutect2, varscan2
- NSD1 | c.438C>T p.I146= | Silent (SNP) | VAF 61/153 reads (40%) | catalogued as COSV61775355; called by muse, mutect2, varscan2
- NUDT22 | c.627C>T p.I209= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs753276122, COSV99655606; called by muse, varscan2
- OR10AG1 | c.651G>A p.L217= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as COSV100400149, COSV56632258; called by muse, mutect2, varscan2
- OR4B1 | c.237C>T p.F79= | Silent (SNP) | VAF 92/274 reads (34%) | catalogued as COSV58882085; called by muse, mutect2, varscan2
- OR51V1 | c.492C>A p.I164= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as COSV58314921, COSV58316349; called by muse, mutect2, varscan2
- PCDHGA6 | c.1449G>A p.Q483= | Silent (SNP) | VAF 89/238 reads (37%) | catalogued as COSV53935503; called by muse, mutect2, varscan2
- PDCD2L | c.822C>G p.L274= | Silent (SNP) | VAF 148/401 reads (37%) | catalogued as COSV55824961, COSV55825245; called by muse, mutect2, varscan2
- PITRM1 | c.3003C>T p.L1001= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as rs779150706, COSV56530282; called by muse, varscan2
- PKDREJ | c.6514C>T p.L2172= | Silent (SNP) | VAF 54/92 reads (59%) | catalogued as rs1348794886, COSV53548863; called by muse, mutect2, varscan2
- PLA2G2F | c.492C>T p.L164= | Silent (SNP) | VAF 62/132 reads (47%) | catalogued as COSV64279931; called by muse, mutect2, varscan2
- PLCZ1 | c.165C>T p.I55= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs1178453727, COSV56851870; called by muse, mutect2, varscan2
- PLEC | c.9771G>A p.L3257= (on ENST00000322810 / NM_201380.4; = p.L3147= on NM_000445.5) | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1554681877, COSV59629789; called by muse, mutect2, varscan2
- PLPP7 | c.99G>A p.P33= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs768515508, COSV64835952; called by muse, varscan2
- POLN | c.282C>G p.V94= | Silent (SNP) | VAF 69/149 reads (46%) | catalogued as rs1266329190, COSV67024993; called by muse, mutect2, varscan2
- PPP2R2B | c.1134G>A p.S378= (on ENST00000394409; = p.S444= on NM_181674.2) | Silent (SNP) | VAF 73/191 reads (38%) | catalogued as rs762618595, COSV60761871; called by muse, mutect2, varscan2
- PTPRJ | c.786G>A p.L262= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as COSV69251756; called by muse, mutect2, varscan2
- QSOX1 | c.2136C>T p.L712= | Silent (SNP) | VAF 51/86 reads (59%) | catalogued as COSV62580268; called by muse, mutect2, varscan2
- RBBP6 | c.4071A>C p.S1357= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV60504679; called by muse, mutect2, varscan2
- RBBP7 | c.45C>G p.V15= | Silent (SNP) | VAF 65/87 reads (75%) | catalogued as COSV66300749; called by muse, mutect2, varscan2
- RFTN1 | c.1011C>T p.F337= | Silent (SNP) | VAF 69/187 reads (37%) | catalogued as COSV61918540; called by muse, mutect2, varscan2
- RIPK3 | c.912C>T p.F304= | Silent (SNP) | VAF 90/341 reads (26%) | catalogued as COSV53475112; called by muse, mutect2, varscan2
- RMDN3 | c.1185C>T p.L395= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as COSV53023798, COSV99540235; called by muse, mutect2, varscan2
- SETD1A | c.2178C>T p.Y726= | Silent (SNP) | VAF 49/89 reads (55%) | catalogued as rs750394524, COSV52687167; called by muse, mutect2, varscan2
- SLC10A2 | c.849C>G p.L283= | Silent (SNP) | VAF 44/169 reads (26%) | catalogued as COSV55358476; called by muse, mutect2, varscan2
- SLC12A6 | c.57G>A p.P19= | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as rs779094623, COSV62543754; called by muse, mutect2, varscan2
- SLC2A7 | c.216C>T p.L72= | Silent (SNP) | VAF 96/184 reads (52%) | catalogued as COSV68901658; called by muse, mutect2, varscan2
- SLC4A5 | c.1920C>T p.F640= | Silent (SNP) | VAF 94/268 reads (35%) | catalogued as COSV61027047; called by muse, mutect2, varscan2
- SLC8A1 | c.1674G>A p.V558= | Silent (SNP) | VAF 65/188 reads (35%) | catalogued as COSV60478824; called by muse, mutect2, varscan2
- SLMAP | c.1662G>C p.L554= (on ENST00000428312 / NM_001377924.1; = p.L616= on NM_007159.5) | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV55846858; called by muse, mutect2, varscan2
- SRPK1 | c.228C>T p.F76= | Silent (SNP) | VAF 60/151 reads (40%) | catalogued as COSV60412455; called by muse, mutect2, varscan2
- STXBP5 | c.1590C>T p.F530= | Silent (SNP) | VAF 53/135 reads (39%) | catalogued as COSV51651370; called by muse, mutect2, varscan2
- SUN5 | c.1041G>A p.G347= | Silent (SNP) | VAF 65/185 reads (35%) | catalogued as rs868229304, COSV62180932; called by muse, mutect2, varscan2
- SUPT6H | c.2820C>G p.L940= | Silent (SNP) | VAF 70/182 reads (38%) | catalogued as COSV58926999; called by muse, mutect2, varscan2
- TAS1R3 | c.57G>A p.T19= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs368625316; called by muse, varscan2
- TAS2R43 | c.120G>A p.K40= | Silent (SNP) | VAF 24/122 reads (20%) | called by muse, mutect2
- TBCD | c.882G>A p.R294= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as COSV62800229; called by muse, varscan2
- TEKT2 | c.225G>A p.K75= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as rs770894403, COSV52880832; called by muse, mutect2, varscan2
- TMC6 | c.967C>T p.L323= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV59808770; called by muse, mutect2, varscan2
- TMC6 | c.756C>G p.L252= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100129871; called by muse, mutect2, varscan2
- TMPRSS11D | c.999T>C p.S333= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as rs1560535855, COSV52222944; called by muse, mutect2, varscan2
- TNNT3 | c.459G>A p.K153= (on ENST00000397301 / NM_001367846.1; = p.K142= on NM_006757.4) | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV53486208; called by muse, mutect2, varscan2
- TRANK1 | c.2532C>G p.L844= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as rs1330757817, COSV57148260; called by muse, mutect2
- TRAV2 | c.45C>T p.L15= | Silent (SNP) | VAF 51/194 reads (26%) | catalogued as rs941723910; called by muse, mutect2, varscan2
- TRAV5 | c.283C>T p.L95= | Silent (SNP) | VAF 41/122 reads (34%) | called by muse, mutect2, varscan2
- TRIB2 | c.138G>A p.P46= | Silent (SNP) | VAF 119/240 reads (50%) | catalogued as COSV50225154; called by muse, mutect2, varscan2
- TTC9B | c.102C>G p.G34= | Silent (SNP) | VAF 7/9 reads (78%) | called by muse, varscan2
- TTLL5 | c.1539C>G p.L513= | Silent (SNP) | VAF 76/200 reads (38%) | catalogued as COSV54032535; called by muse, mutect2, varscan2
- UBXN7 | c.1026G>A p.E342= | Silent (SNP) | VAF 73/226 reads (32%) | catalogued as COSV56355357; called by muse, mutect2, varscan2
- UHMK1 | c.159C>T p.L53= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV56419839; called by muse, mutect2, varscan2
- UNC5B | c.1155C>T p.F385= | Silent (SNP) | VAF 155/430 reads (36%) | catalogued as rs754467526, COSV58976389; called by muse, mutect2, varscan2
- UQCRC1 | c.423G>A p.P141= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs746906806, COSV52551498; called by muse, mutect2, varscan2
- USH2A | c.12519G>A p.L4173= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as COSV100230841, COSV56361121; called by muse, mutect2, varscan2
- UTP14A | c.1464G>A p.Q488= | Silent (SNP) | VAF 120/166 reads (72%) | catalogued as COSV64086759; called by muse, mutect2, varscan2
- XXYLT1 | c.423C>T p.F141= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs1456821773, COSV58751499; called by muse, mutect2, varscan2
- ZBTB49 | c.231G>A p.Q77= | Silent (SNP) | VAF 57/137 reads (42%) | catalogued as COSV61924909; called by muse, mutect2, varscan2
- ZC3H12D | c.27C>T p.F9= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV101116790, COSV66324220; called by muse, mutect2, varscan2
- ZDHHC19 | c.222C>T p.F74= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as rs750064079, COSV56348593; called by muse, mutect2, varscan2
- ZNF227 | c.1281G>A p.Q427= | Silent (SNP) | VAF 51/150 reads (34%) | catalogued as COSV57312128; called by muse, mutect2, varscan2
- ZNF335 | c.2304C>G p.L768= | Silent (SNP) | VAF 48/139 reads (35%) | catalogued as COSV59817393; called by muse, mutect2, varscan2
- ZNF521 | c.2022C>T p.P674= | Silent (SNP) | VAF 96/265 reads (36%) | catalogued as COSV64126112; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | chr3:51977875 T>C | 5'Flank (SNP) | VAF 78/205 reads (38%) | catalogued as COSV56472546; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825346 G>C | 5'Flank (SNP) | VAF 41/57 reads (72%) | catalogued as rs1291757886; called by muse, mutect2, varscan2
- C9orf163 | n.1496G>C | RNA (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- FN1 | c.3797-1311C>G | Intron (SNP) | VAF 45/73 reads (62%) | catalogued as COSV60551629; called by muse, mutect2, varscan2
- MAP4 | c.1999+4613C>T | Intron (SNP) | VAF 27/78 reads (35%) | catalogued as rs1224016580, COSV53137071; called by muse, mutect2, varscan2
- METTL16 | n.989C>T | RNA (SNP) | VAF 18/42 reads (43%) | catalogued as rs368828666; called by muse, mutect2, varscan2
- PPHLN1 | c.1024+57C>G | Intron (SNP) | VAF 34/82 reads (41%) | catalogued as COSV56730411; called by muse, mutect2, varscan2
- PWWP3A | chr19:1376553 G>T | 3'Flank (SNP) | VAF 43/129 reads (33%) | catalogued as rs1378983939, COSV100261699; called by muse, mutect2, varscan2
- SMIM29 | c.*109C>G | 3'UTR (SNP) | VAF 21/55 reads (38%) | catalogued as COSV58988411; called by muse, mutect2, varscan2
- SSPOP | n.3551C>T | RNA (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2
- SSPOP | n.9874C>T | RNA (SNP) | VAF 46/133 reads (35%) | catalogued as rs767860297, COSV65127718; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 21/39 reads (54%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28581042 G>C | 3'Flank (SNP) | VAF 65/135 reads (48%) | called by muse, mutect2, varscan2
- TTN | c.10303+1162C>T | Intron (SNP) | VAF 82/186 reads (44%) | catalogued as COSV100619139, COSV60011311; called by muse, mutect2, varscan2
